Gene-level copy-number profile of tumor specimen HTMCP-02-06-01050-01A from CGCI case HTMCP-02-06-01050, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung.
Specimen HTMCP-02-06-01050-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 31023f81-301f-483e-8b3d-d56b2364e9ad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-06-01050-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/767a9c8a-4284-4819-93c6-9bac3974771d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 7,688; copy number 2: 28,254; copy number 3: 18,871; copy number 4: 3,390; copy number 5: 289; copy number 6: 187; copy number 7: 96; copy number 8: 16; copy number 9: 12; copy number 13: 33; copy number 14: 18; copy number 24: 2.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:86,784,913–87,169,204, 8 genes: AL049597.1, SELENOF, HS2ST1, AL121989.1, AC093155.3, AC093155.2, AC093155.1, LINC01140.
- chr1:114,704,469–115,698,224, 21 genes: NRAS, CSDE1, RNY1P13, SIKE1, NR1H5P, SYCP1, TSHB, TSPAN2, LINC01765, AL049825.1, NGF-AS1, NGF, AL512638.3, AL512638.1, AL512638.2, ELOCP20, CNOT7P2, AL592436.2, RN7SL420P, AL592436.1, VANGL1.
- chr4:180,573,464–180,574,027, 1 gene: NDUFB5P1.
- chr8:128,405,269–128,564,679, 1 gene: LINC00824.
- chr15:34,379,068–34,521,791, 8 genes (within-gene range 0–2): GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:34,528,290–34,528,371, 1 gene (within-gene range 0–2): MIR1233-2.
- chr16:49,066,567–49,281,838, 5 genes: MTND4LP25, AC044798.3, AC044798.1, AC044798.2, CBLN1.
- chr16:49,297,143–49,299,762, 1 gene: AC007614.2.
- chr22:46,762,617–47,175,699, 3 genes (within-gene range 0–3): TBC1D22A, TBC1D22A-AS1, FP325331.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 653 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:143,855,739–143,856,142, 1 gene, copy number 5: AC107421.1.
- chr3:150,926,163–150,972,727, 1 gene, copy number 5 (within-gene range 4–5): CLRN1.
- chr3:180,989,762–188,003,990, 175 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:190,305,707–190,449,876, 3 genes, copy number 5: CLDN1, CLDN16, TMEM207.
- chr5:145,858,521–146,120,412, 5 genes, copy number 5 (within-gene range 3–5): GRXCR2, SH3RF2, AC005351.1, PLAC8L1, AC091887.1.
- chr6:63,719,980–65,838,039, 10 genes, copy number 5 (within-gene range 4–5): EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4.
- chr6:69,672,757–70,212,468, 5 genes, copy number 5: LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15.
- chr6:163,586,583–163,588,165, 1 gene, copy number 5: AL445307.1.
- chr7:38,239,580–38,249,572, 1 gene, copy number 8: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 8: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:51,471,717–53,036,925, 9 genes, copy number 5: AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC079763.1, AC006320.1, SGO1P2, AC074397.1, POM121L12.
- chr7:122,994,704–127,253,093, 45 genes, copy number 5 (within-gene range 3–5): TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A, AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P, AC004925.1, GPR37, C7orf77, POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93, AC003975.1, AC000372.1, GRM8, AC002057.2, AC000374.1, AC002057.1, AC000367.1.
- chr7:127,215,127–127,229,927, 1 gene, copy number 5 (within-gene range 4–5): GRM8-AS1.
- chr7:142,939,343–148,420,998, 92 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr7:147,378,017–158,587,823, 225 genes, copy number 6–24 (within-gene range 3–24) (broad region; genes not listed).
- chr8:42,541,155–43,544,057, 38 genes, copy number 5 (within-gene range 3–5): SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2.
- chr8:46,028,804–46,028,892, 1 gene, copy number 6: AC118650.1.
- chr19:29,205,320–30,713,538, 25 genes, copy number 5–7 (within-gene range 2–7): UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536.

Autosomal genes at a single copy (total copy number 1): 7,176. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
